Somatic mutation profile of tumor specimen TCGA-A4-7584-01A (aliquot TCGA-A4-7584-01A-11D-2136-08) from TCGA case TCGA-A4-7584, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 59.6 years (21,782 days).
Specimen TCGA-A4-7584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2f86db0-0d5f-4548-880b-21990b17e6cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7584-10A (Blood Derived Normal), aliquot TCGA-A4-7584-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3938c3a7-24e5-41bd-8e78-9de302cfeac3

The open-access MAF lists 75 somatic variants for this specimen: 58 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 16, Frame Shift Del 5, Frame Shift Ins 4, Nonsense Mutation 3, Splice Site 2, Splice Region 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 91/164 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); catalogued as COSV59318979; called by muse, mutect2, varscan2
- AKR1C3 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV101003069, COSV65910655; called by muse, mutect2, varscan2
- ANKMY2 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV61011932; called by muse, mutect2, varscan2
- ANKMY2 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61011350; called by muse, mutect2, varscan2
- AP2M1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV53048525; called by muse, mutect2, varscan2
- C19orf57 | c.1669-1G>C p.X557_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV60968652; called by muse, mutect2, varscan2
- CARD10 | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs757574816, COSV52657455; called by muse, mutect2, varscan2
- CCDC178 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55777503; called by muse, mutect2, varscan2
- CIAPIN1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747188516, COSV67953409; called by muse, mutect2, varscan2
- CLCN7 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51971088; called by muse, mutect2, varscan2
- CNTN1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV61637658, COSV61640793; called by muse, mutect2, varscan2
- COG1 | c.2138C>A p.A713D | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55430231; called by muse, mutect2, varscan2
- COLGALT2 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62729221; called by muse, mutect2, varscan2
- DDO | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64470212; called by muse, mutect2, varscan2
- DNAH2 | c.11501G>A p.R3834Q | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs368019673; called by muse, mutect2, varscan2
- DUOX1 | c.4484G>T p.R1495L | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52050869; called by muse, mutect2, varscan2
- DYNC2H1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs1379999948, COSV62096322; called by muse, mutect2, varscan2
- EMILIN2 | c.3017G>T p.G1006V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54424497; called by muse, mutect2, varscan2
- FAM71B | c.1258C>G p.P420A | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57229473; called by muse, mutect2, varscan2
- FDXR | c.620T>G p.I207S (on ENST00000293195 / NM_024417.5; = p.I213S on NM_004110.6) | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53122647; called by muse, mutect2, varscan2
- FIP1L1 | c.815+1G>C p.X272_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | catalogued as COSV60994275, COSV60997139; called by muse, mutect2, varscan2
- GAL3ST1 | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV58892860; called by muse, mutect2, varscan2
- GDF5 | c.1277C>A p.A426D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65501861; called by muse, mutect2, varscan2
- HELZ | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV62378930; called by muse, mutect2, varscan2
- HMGB4 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV53920739, COSV99595016; called by muse, mutect2, varscan2
- INTS11 | c.1049T>C p.M350T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV60088764; called by muse, mutect2, varscan2
- KIF5A | c.2767C>T p.R923W | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1231571339, COSV54055523; called by muse, mutect2, varscan2
- MITF | c.349A>T p.K117* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV58884270; called by muse, mutect2, varscan2
- MRPL17 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56618514; called by muse, mutect2, varscan2
- MUC16 | c.27974C>A p.A9325D | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV67457550, COSV67472460; called by muse, mutect2, varscan2
- NXPE3 | c.847A>T p.S283C | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV56290320; called by muse, mutect2, varscan2
- PARD6B | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs768668443, COSV65404029; called by muse, mutect2, varscan2
- PCLO | c.5555A>T p.H1852L | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV100431198, COSV61640430; called by muse, mutect2, varscan2
- PCSK1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.625); catalogued as COSV60735926; called by muse, mutect2, varscan2
- PLCH2 | c.2380A>G p.I794V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as rs1447598164, COSV53944388; called by mutect2, varscan2
- RAD54L2 | c.4175C>G p.S1392C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.221); catalogued as COSV56578990; called by muse, mutect2, varscan2
- SCAF1 | c.3835A>C p.K1279Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59190847, COSV59191643; called by muse, mutect2, varscan2
- SFPQ | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV61758764; called by muse, mutect2, varscan2
- SSBP3 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV62575050; called by muse, mutect2, varscan2
- SYNE1 | c.16940C>T p.A5647V (on ENST00000367255 / NM_182961.4; = p.A5576V on NM_033071.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV55005681; called by muse, mutect2, varscan2
- TACR2 | c.314T>A p.F105Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV64822371; called by muse, mutect2, varscan2
- USP20 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59614859; called by muse, mutect2, varscan2
- VRK1 | c.583T>A p.L195M | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53709803; called by muse, mutect2, varscan2
- WDR91 | c.2120T>A p.L707Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60370322; called by muse, mutect2, varscan2
- ZNF317 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV56110055; called by muse, mutect2, varscan2
- ZNF543 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1209689002, COSV58627835; called by muse, mutect2, varscan2
- ZNF609 | c.373T>C p.S125P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58584290; called by muse, mutect2, varscan2
- ABCB9 | c.1288del p.Y430Tfs*11 | Frame Shift Del (DEL) | VAF 50/182 reads (27%) | called by mutect2, pindel, varscan2
- ABL2 | c.1046-3del | Splice Region (DEL) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.1308dup p.C437Mfs*13 | Frame Shift Ins (INS) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- DUOX1 | c.3852del p.S1285Qfs*3 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- EXOC3L2 | c.1990del p.R664Gfs*132 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- ITGB4 | c.4972_4977dup p.Q1658_L1659dup | In Frame Ins (INS) | VAF 56/125 reads (45%) | called by mutect2, varscan2
- KDM6A | c.438del p.Q147Sfs*33 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | called by mutect2, pindel, varscan2
- KRT32 | c.643dup p.D215Gfs*7 | Frame Shift Ins (INS) | VAF 72/153 reads (47%) | called by mutect2, pindel, varscan2
- LIX1L | c.636dup p.G213Wfs*35 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- MANSC1 | c.665del p.N222Mfs*2 | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- RMDN3 | c.673_677dup p.L227Vfs*70 | Frame Shift Ins (INS) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- AP001781.2 | c.132T>C p.D44= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs782274136, COSV52788918; called by mutect2, varscan2
- CD22 | c.813C>T p.N271= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs1194237510, COSV50055088; called by muse, mutect2, varscan2
- DCDC1 | c.5184C>A p.V1728= (on ENST00000597505 / NM_001367979.1; = p.V835= on NM_020869.3) | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs759369961, COSV57997467, COSV57999805; called by muse, mutect2, varscan2
- DUOX1 | c.4485T>A p.R1495= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as rs947864083, COSV52050874; called by muse, mutect2, varscan2
- EFCAB5 | c.3312G>C p.L1104= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV57931428; called by muse, mutect2
- GCC2 | c.4440C>T p.T1480= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV59177050; called by muse, mutect2, varscan2
- GPR1 | c.1042C>T p.L348= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV67976622, COSV67976940; called by muse, mutect2, varscan2
- GUCY2C | c.2787T>G p.A929= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV53791149; called by muse, mutect2, varscan2
- HMCN1 | c.11160G>A p.Q3720= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as COSV54907459; called by muse, mutect2, varscan2
- KCTD4 | c.168C>T p.D56= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as rs915565506, COSV61240505; called by muse, mutect2, varscan2
- LILRB1 | c.861C>A p.G287= (on ENST00000427581; = p.G251= on NM_006669.6) | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100207514, COSV61118920; called by muse, mutect2, varscan2
- NAV3 | c.7095C>T p.C2365= (on ENST00000397909 / NM_001024383.2; = p.C2343= on NM_014903.6) | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs763140795, COSV57085656; called by muse, mutect2, varscan2
- NEMF | c.2658G>A p.Q886= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV53592255; called by muse, mutect2, varscan2
- PLRG1 | c.543A>G p.K181= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV57423801; called by muse, mutect2, varscan2
- WASHC4 | c.1221C>G p.V407= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV59890145; called by muse, mutect2, varscan2
- ZNF335 | c.3426C>G p.T1142= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV59818265; called by muse, mutect2, varscan2
- TTN | c.10361-4743C>G | Intron (SNP) | VAF 39/86 reads (45%) | catalogued as COSV100610286; called by muse, mutect2, varscan2
